Gene-level copy-number profile of tumor specimen TCGA-AF-6136-01A from TCGA case TCGA-AF-6136, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.5 years (26,490 days).
Specimen TCGA-AF-6136-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.37eccf41-3927-4066-8dc6-7ad461de40d8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AF-6136-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93d1e69a-fc8b-4248-b9c3-a0d43caebde0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,148; copy number 2: 21,484; copy number 3: 14,531; copy number 4: 19,431; copy number 5: 1,573; copy number 6: 234; copy number 7: 23; copy number 8: 1,391.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AF-6136-01A-11D-1825-01): tumor purity 0.58, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,221 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:115,471,941–121,580,524, 144 genes, copy number 6 (broad region; genes not listed).
- chr7:70,972–4,269,000, 87 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:46,261,064–48,061,304, 23 genes, copy number 7: AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57.
- chr7:53,776,136–54,677,369, 15 genes, copy number 6: RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3.
- chr7:62,275,361–64,150,721, 75 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:31,618,124–50,422,316, 363 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 8 (broad region; genes not listed).
- chr18:47,390–7,461,135, 150 genes, copy number 5 (broad region; genes not listed).
- chr20:24,949,269–64,313,132, 967 genes, copy number 5 (broad region; genes not listed).
- chr22:25,351,418–25,437,823, 4 genes, copy number 5 (within-gene range 2–5): LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1.
- chr22:25,455,646–25,479,971, 2 genes, copy number 5: MIR6817, AL008721.2.

Autosomal genes at a single copy (total copy number 1): 1,148. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
